Somatic mutation profile of tumor specimen BA2438D (aliquot aq-BA2438D) from BEATAML1.0 case 2560, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.2 years (27,111 days).
Specimen BA2438D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64bc30e0-dafb-457c-b284-572459803376.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2340D (Solid Tissue Normal), aliquot aq-BA2340D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/daf8368d-74ed-41be-baae-399ca61a3c69

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, Frame Shift Del 2, Nonsense Mutation 1, Splice Region 1, 5'Flank 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTN6 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs745410696, COSV63178028; called by muse, mutect2, varscan2
- HECW2 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1366307621, COSV53665948; called by muse, mutect2, varscan2
- MUC16 | c.23978G>A p.S7993N | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.263); catalogued as rs1337554415; called by muse, mutect2, varscan2
- OR14J1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1022608299, COSV65845778; called by muse, mutect2, varscan2
- POM121L12 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs200929126, COSV68692625; called by muse, mutect2, varscan2
- RNF126 | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as rs773845769; called by muse, varscan2
- SIGLEC11 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.826); catalogued as rs758493747; called by muse, varscan2
- SIPA1L3 | c.3542C>A p.A1181D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.105); catalogued as COSV55922226; called by muse, mutect2
- VTI1A | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747671848, COSV67579357; called by muse, mutect2, varscan2
- BCOR | c.4434_4441del p.V1479Lfs*8 (on ENST00000378444 / NM_001123385.2; = p.V1445Lfs*8 on NM_017745.6) | Frame Shift Del (DEL) | VAF 68/86 reads (79%) | called by mutect2, pindel, varscan2
- CD44 | c.232A>G p.R78G | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CYP1B1 | c.569T>G p.F190C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2
- DICER1 | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 146/349 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ETV6 | c.641dup p.A215Gfs*2 | Frame Shift Ins (INS) | VAF 29/78 reads (37%) | called by mutect2, varscan2
- MIGA1 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2, varscan2
- PYCR1 | c.725del p.L242Cfs*49 | Frame Shift Del (DEL) | VAF 60/142 reads (42%) | called by mutect2, pindel, varscan2
- TADA2A | c.626A>T p.D209V | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TEX36 | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAPPC12 | c.1776+7G>T | Splice Region (SNP) | VAF 44/111 reads (40%) | called by muse, mutect2, varscan2
- PFAS | c.222T>A p.A74= | Silent (SNP) | VAF 52/117 reads (44%) | called by muse, mutect2, varscan2
- POSTN | c.891C>T p.S297= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs762780222, COSV101123459, COSV65712171; called by muse, mutect2, varscan2
- ODF2 | chr9:128456101 C>A | 5'Flank (SNP) | VAF 6/55 reads (11%) | catalogued as rs908789709; called by muse, mutect2
- TPTE | c.-18G>A | 5'UTR (SNP) | VAF 63/369 reads (17%) | catalogued as rs1196907457; called by muse, mutect2, varscan2
